Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A3XZ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A3XZ-01A (Primary Tumor).

[page 1 of 3]
Specimen:

Received:
Spec Type: SURGICAL P

Status:
Subm Dr:

PREOPERATIVE DIAGNOSIS

LEFT BREAST CANCER INVASIVE

OPERATION PERFORMED

DATE:

DOCTOR(S):

PROCEDURE: MASTECTOMY COMPLETE/SIMPLE W/ SENTINEL NODE BX

TISSUE REMOVED

- A. LT SIMPLE MASTECTOMY -
- B. LT AXILLA SENTINEL NODE #1
- C. LT UPPER INNER CORE BX -
- D. LT BREAST SUPERFICIAL MARGIN -
- E. LT AXILLA SENTINEL NODE #2

GROSS DESCRIPTION

PART A RECEIVED FRESH LABELED [REDACTED] LEFT SIMPLE MASTECTOMY STITCH 12 O'CLOCK, IS A LEFT SIMPLE MASTECTOMY SPECIMEN MEASURING 16 X 16 X 3.5 CM. THE NIPPLE IS UNREMARKABLE WITHIN A 7.5 X 4.2 CM SKIN ELLIPSE. BLUE DYE IS NOTED IN THE SUPERIOR 12 O'CLOCK AREA OF THE BREAST. THE SUPERFICIAL ASPECT IS MARKED WITH BLUE INK, THE DEEP WITH BLACK. AN M CLIP IS IDENTIFIED IN THE UPPER INNER QUADRANT MEDIAL ASPECT, ASSOCIATED WITH A PINK-TAN NODULE AT THE SUPERFICIAL MARGIN MEASURING 0.9 X 0.5 X 1.2 CM. THIS IS 1.3 CM FROM THE DEEP MARGIN, 1 CM FROM THIS IS A 0.3 CM FIRM GRAY-TAN AREA WHICH IS 1 CM FROM THE SUPERFICIAL MARGIN AND 1.1 CM FROM THE DEEP MARGIN GROSSLY. IN THE 11 O'CLOCK AREA THERE IS AN ELONGATED IRREGULAR PINK-TAN FIRM AREA WHICH ALSO EXTENDS GROSSLY TO THE SUPERFICIAL MARGIN. THIS MEASURES 3.5 X 0.9 AND IS 1.5 CM IN GREATEST DIMENSION. THIS LESION IS GROSSLY 3 CM FROM THE FIRST DESCRIBED LESION. THIS LESION GROSSLY EXTENDS TOWARDS THE SUPERFICIAL MARGIN AND IS 1.2 CM FROM THE DEEP MARGIN. THE BREAST TISSUE ITSELF HAS AN OVERALL INDURATED QUALITY TO PALPATION WITH A DIFFUSE YELLOW-GRAY APPEARANCE. THE INFERIOR AND LATERAL ASPECTS DEMONSTRATE A MORE FATTY APPEARANCE. ALSO IN THE AREA OF THE UPPER INNER QUADRANT, THE PARENCHYMA HAS MULTIPLE SMALL PALPABLE LESIONS. THIS IS IN THE AREA OF THE BLUE DYE. IT IS SECTIONED TO DEMONSTRATE THIS WHICH IS SLIGHTLY INFERIOR AND TOWARD THE NIPPLE FROM THE SECOND DESCRIBED LESION SUBMITTED IN A10 (MIRROR IMAGE TO PROTOCOL). RANDOM TISSUE IS ALSO TAKEN FROM THE 9 O'CLOCK AREA WHICH HAS THIS DIFFUSE INDURATED QUALITY. THE SECTIONS ARE SUBMITTED AS FOLLOWS: A1--NIPPLE AND SKIN (MIRROR IMAGE TO PROTOCOL), A2--10 O'CLOCK PERIPHERAL LESION TO INCLUDE SUPERFICIAL AND DEEP MARGINS (MIRROR IMAGE TO PROTOCOL), A3--10 O'CLOCK LESION (MIRROR IMAGE TO PROTOCOL), A4--SMALL 0.3 CM NODULE WITHIN TISSUE (MIRROR IMAGE TO PROTOCOL), A5--SECTION OF 11 O'CLOCK LESION (MIRROR IMAGE TO PROTOCOL), A6 THROUGH A8--FOR CROSS-SECTION OF 11 O'CLOCK LESION TO INCLUDE THE MOST SUPERIOR AND SUPERFICIAL, DEEP AND SUPERFICIAL INFERIOR ASPECT OF LESIONS TO INCLUDE SUPERFICIAL MARGIN RESPECTIVELY, A9--11 O'CLOCK LESION (MIRROR IMAGE TO

ICD-O-3

Carcinoma, infiltrating duct, NOS
8500/3

Site: breast, NOS

C50.9

5-23-12 ep

[page 2 of 3]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Spec Type: SURGICAL P

Subm Dr:

GROSS DESCRIPTION

(Continued)

PROTOCOL), A10--TISSUE UPPER OUTER QUADRANT, A11--TISSUE 9 O'CLOCK A REGION, A12--UPPER OUTER QUADRANT 4 CM FROM THE 11 O'CLOCK LESION (MIRROR IMAGE TO PROTOCOL), A13--LOWER OUTER QUADRANT 8 CM FROM THE LESION (MIRROR IMAGE TO PROTOCOL), A14--LOWER INNER QUADRANT.

PART B RECEIVED FRESH LABELED [REDACTED], LEFT AXILLA FIRST SENTINEL NODE HOT AND BLUE, IS A AN OVOID PORTION OF PINK-TAN SOFT TISSUE MEASURING 2.5 X 1.3 X 1.0 CM. SECTIONING REVEALS A 1.8 CM GROSSLY UNREMARKABLE LYMPH NODE WITHOUT OBVIOUS BLUE COLORATION. ONE HALF IS SUBMITTED LABELED B. THE REMAINDER IS SUBMITTED PER PROTOCOL.

PART C RECEIVED LABELED [REDACTED] LEFT UPPER INNER CORE BIOPSY SITE, IS AN UNORIENTED ELLIPTICAL PORTION OF BROWN SKIN AND UNDERLYING INDURATED FATTY TISSUE. THE SKIN ELLIPSE IS 1.4 X 0.5 CM. THE UNDERLYING TISSUE MEASURES 2.1 X 0.9 X 1.8 CM. ON THE SKIN SURFACE THERE IS A RAISED CENTRAL LESION 0.5 CM DIAMETER. THE MARGIN IS MARKED WITH INK. THE SPECIMEN IS SECTIONED ACROSS THE NARROW MARGIN OF THE SKIN AND THE 2 EXTREME ENDS (ELLIPTICAL END OF THE SKIN ARE SUBMITTED IN C1 WITH THE CENTRAL TISSUE IN C2).

PART D RECEIVED LABELED [REDACTED] LEFT BREAST SUPERFICIAL MARGIN IS AN IRREGULAR ELONGATED FRAGMENT OF YELLOW-PINK FATTY TISSUE MEASURING 8.5 X 2.1 X 0.5 CM IN GREATEST DIMENSION. THE SPECIMEN IS NOT OTHERWISE ORIENTED. ONE SIDE HAS A DULL APPEARANCE AND IS MARKED WITH BLUE INK. THE OPPOSITE SIDE IS MARKED YELLOW. THIS IS SECTIONED AND ENTIRELY SUBMITTED LABELED D1 THROUGH D5.

PART E RECEIVED FRESH LABELED [REDACTED] LEFT AXILLA SECOND SENTINEL NODE HOT, IS AN OVOID PORTION OF YELLOW-PINK FATTY TISSUE MEASURING 2.9 X 1.7 X 1.0 CM. SECTIONING REVEALS A 1.8 CM GROSSLY UNREMARKABLE LYMPH NODE SUBMITTED ENTIRELY LABELED E.

PATH PROCEDURES

PROCEDURES:

88307/5, IMMUNOPEROXIDAS/2, A BLK/14, BBX X6, C BLK/2, D BLK/5, EBX X6

FINAL DIAGNOSIS

PART A LEFT SIMPLE MASTECTOMY: MULTICENTRIC IN SITU AND INFILTRATING DUCT CARCINOMA WITH AT LEAST FOUR SEPARATE FOCI OF TUMOR PRESENT. THE 10 O'CLOCK NODULE SHOWED IN SITU AND MODERATELY DIFFERENTIATED INFILTRATING DUCT CARCINOMA, NUCLEAR GRADE III/III WITH A HIGH MITOTIC INDEX, ASSOCIATED WITH A PREVIOUS BIOPSY SITE WITH APPROXIMATELY 1.0 CM OF IN SITU AND 1.2 CM OF INVASIVE CARCINOMA. THIS LESION EXTENDED TO WITHIN LESS THAN 1 MM OF THE SUPERFICIAL MARGIN. IN THE 11 O'CLOCK POSITION, APPROXIMATELY 1.9 CM OF INVASIVE CARCINOMA WAS PRESENT ASSOCIATED WITH 2.2 CM OF DUCT CARCINOMA IN SITU SHOWING SIMILAR NUCLEAR GRADE AND HISTOMORPHOLOGY. THIS LESION WAS 5 MM FROM THE DEEP MARGIN AND WAS

10^u DC13 1cm
1DC 1.2cm
2/3/3
11^u DC15 2.2cm
1DC 1.9cm
2/3/3

[page 3 of 3]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Spec Type: SURGICAL P
(Continued)

Status:

Subm Dr:

FINAL DIAGNOSIS

ASSOCIATED WITH A PREVIOUS BIOPSY SITE. THE PREVIOUS BIOPSY SITE EXTENDED TO THE SUPERFICIAL MARGIN. A SECTION OF BREAST TISSUE FROM THE UPPER OUTER QUADRANT OF THE BREAST SHOWED APPROXIMATELY 1.1 CM OF DUCT CARCINOMA IN SITU AND 0.5 CM OF INVASIVE CARCINOMA WITH SIMILAR HISTOMORPHOLOGY. AN ADDITIONAL NODULE FROM THE UPPER INNER QUADRANT OF THE BREAST SHOWED CHANGES OF A PREVIOUS BIOPSY SITE BUT NO RESIDUAL TUMOR.

UOQ
DCIS 1.1cm IDC 0.5cm

PARTS B AND E LEFT AXILLARY SENTINEL LYMPH NODES NUMBERS 1 AND 2, BIOPSIES: LYMPH NODES WITH NO EVIDENCE OF METASTATIC DISEASE, SUPPORTED BY NEGATIVE CYTOKERATIN IMMUNOHISTOCHEMICAL STAINING.

9/2 SN

PART C LEFT UPPER INNER CORE BIOPSY SITE, REEXCISION: SKIN AND BREAST TISSUE CONTAINING A PREVIOUS NEEDLE CORE BIOPSY SITE ASSOCIATED WITH REACTIVE FIBROSIS AND INFLAMMATION. NO RESIDUAL TUMOR IDENTIFIED. THE PREVIOUS BIOPSY CHANGES EXTEND INTO THE DERMIS.

UIC re-exc @ tumor
B x A

PART D LEFT BREAST SUPERFICIAL MARGIN, REEXCISION: ADIPOSE TISSUE WITH NO EVIDENCE OF MALIGNANCY.

CODE

1

Signed

(signature on file)

(prelim.)

IHC/NA Discrepancy		/

Source: NCI Genomic Data Commons file 2e2d7f3d-8d50-4b3b-bfae-d6cc0ede2bfd (TCGA-A2-A3XZ.A7B6FCF6-1B81-40B5-AD92-54681CBC8FE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).